Somatic mutation profile of tumor specimen TCGA-UY-A8OC-01A (aliquot TCGA-UY-A8OC-01A-11D-A364-08) from TCGA case TCGA-UY-A8OC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-UY-A8OC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 053cc86b-a9f2-411e-a5b7-7ba8ac4cb670.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A8OC-10A (Blood Derived Normal), aliquot TCGA-UY-A8OC-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3f18fd9-18a1-4343-bcbf-aff130e4eb58

The open-access MAF lists 103 somatic variants for this specimen: 78 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 69, Silent 25, Nonsense Mutation 6, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 60/77 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACO2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53442899; called by muse, varscan2
- AKAP11 | c.5144C>T p.S1715L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs946478711, COSV50297038; called by muse, mutect2, varscan2
- AP1G2 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV55338234; called by muse, mutect2, varscan2
- APOB | c.2968G>A p.A990T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs139434026; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ARHGEF7 | c.440C>T p.S147L (on ENST00000375741 / NM_001113511.2; = p.S126L on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.407); catalogued as rs750993031, COSV54541804, COSV54543563; called by muse, mutect2, varscan2
- ATP13A2 | c.2681C>T p.S894L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs376348581; called by muse, mutect2, varscan2
- BCAS3 | c.1870G>A p.E624K (on ENST00000390652 / NM_001353144.2; = p.E609K on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66774328; called by muse, mutect2, varscan2
- BICD1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV55679566, COSV99862824; called by muse, mutect2
- CACTIN | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1178679703, COSV50268213; called by muse, mutect2, varscan2
- CALR3 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as rs143334090; called by muse, mutect2
- CDH4 | c.2732G>A p.G911E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64655130; called by muse, mutect2, varscan2
- CNNM4 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.938); catalogued as rs369263433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.6511G>A p.G2171R | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55090010, COSV99797982; called by muse, mutect2, varscan2
- COX11 | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV54802976; called by muse, mutect2, varscan2
- CYB561D1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV60204877; called by muse, mutect2, varscan2
- CYP27B1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV56985313; called by muse, mutect2, varscan2
- DHRS2 | c.675+3G>T | Splice Region (SNP) | VAF 8/40 reads (20%) | catalogued as COSV51631966; called by muse, varscan2
- DIAPH2 | c.3197G>A p.G1066D | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61270382, COSV61293476; called by muse, mutect2, varscan2
- DISP1 | c.3047T>C p.I1016T | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52659106; called by muse, mutect2, varscan2
- ERC2 | c.2503G>A p.A835T | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs751986725, COSV55623028; called by muse, mutect2, varscan2
- FCRLA | c.845G>C p.R282T (on ENST00000367959; = p.R259T on NM_032738.4) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV52685970; called by muse, mutect2, varscan2
- FHDC1 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV52599996; called by muse, mutect2
- FHDC1 | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as rs1196323978, COSV99471422; called by muse, mutect2, varscan2
- FHDC1 | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV52600002; called by muse, varscan2
- GAS6 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV59850443; called by muse, mutect2, varscan2
- GRM5 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1409555487, COSV100555021, COSV59605587; called by muse, mutect2, varscan2
- HABP2 | c.1312G>C p.D438H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs144211693; called by muse, mutect2, varscan2
- IL12RB2 | c.2246G>C p.S749T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as COSV52023564; called by muse, mutect2, varscan2
- ITGAE | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs755450329, COSV53993961; called by muse, mutect2, varscan2
- KCNN2 | c.743C>A p.S248Y (on ENST00000264773; = p.S460Y on NM_021614.4) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53288816; called by muse, mutect2, varscan2
- KIAA1217 | c.5092G>A p.D1698N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV56816869; called by muse, mutect2, varscan2
- KIF15 | c.4120C>T p.R1374C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs780041617, COSV58160343; called by muse, mutect2, varscan2
- KRT4 | c.110G>C p.G37A | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV53407356; called by muse, mutect2, varscan2
- LAMB4 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.492); catalogued as rs867035751, COSV52719642; called by muse, mutect2, varscan2
- LMOD2 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV71755647; called by muse, mutect2, varscan2
- LPA | c.5980C>G p.L1994V | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs897240051, COSV60302123; called by muse, mutect2, varscan2
- LRP6 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs376188127; called by muse, mutect2, varscan2
- MAML2 | c.2170G>A p.G724S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.643); catalogued as COSV73263506; called by muse, mutect2, varscan2
- MCM4 | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.21); PolyPhen benign (0.211); catalogued as COSV100031627; called by muse, mutect2, varscan2
- MOSPD2 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV66860120; called by muse, mutect2, varscan2
- NBEAL1 | c.4138T>C p.S1380P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV101495739; called by mutect2, varscan2
- NOTCH2 | c.6508A>T p.I2170F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV56691733; called by muse, mutect2, varscan2
- NPC1 | c.2898C>G p.F966L | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52578862; called by muse, mutect2, varscan2
- NR3C1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51542984; called by muse, mutect2, varscan2
- NSMCE1 | c.424A>G p.R142G | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV63864300; called by muse, mutect2, varscan2
- NT5C2 | c.1079C>G p.S360* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100583590; called by muse, mutect2, varscan2
- OR6C75 | c.5G>C p.R2T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); catalogued as COSV58552263; called by muse, mutect2, varscan2
- OR9K2 | c.976A>T p.K326* (on ENST00000305377; = p.K304* on NM_001005243.1) | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100543862, COSV59531871; called by muse, mutect2, varscan2
- PARD3 | c.3343C>T p.Q1115* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100631443; called by muse, mutect2, varscan2
- PAX3 | c.724C>G p.H242D | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60588525; called by muse, mutect2, varscan2
- PPP4R1 | c.2065G>T p.E689* (on ENST00000400556 / NM_001042388.3; = p.E672* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 76/123 reads (62%) | catalogued as rs754706117, COSV53283395; called by muse, mutect2, varscan2
- PTPN13 | c.5231C>G p.S1744C (on ENST00000411767 / NM_080683.3; = p.S1725C on NM_006264.3) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV57407911; called by muse, mutect2, varscan2
- QRSL1 | c.99G>C p.K33N | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV64687494; called by muse, mutect2, varscan2
- RAD51AP2 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV67588085; called by muse, mutect2, varscan2
- ROR2 | c.1061A>G p.D354G | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.161); catalogued as COSV65219203; called by muse, mutect2, varscan2
- SALL2 | c.2405C>G p.S802* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100444456; called by muse, mutect2, varscan2
- SCFD2 | c.1120A>G p.I374V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV66371619; called by muse, mutect2, varscan2
- SEMA3D | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs767707636, COSV52389202; called by muse, mutect2, varscan2
- SIPA1L3 | c.2225C>G p.S742C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55914400; called by muse, mutect2, varscan2
- SLC27A2 | c.316T>A p.C106S | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as rs1394828168, COSV51059153; called by muse, mutect2, varscan2
- SNAP29 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs751485587, COSV53142692, COSV53144213; called by muse, mutect2, varscan2
- SOAT1 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62654284; called by muse, mutect2, varscan2
- SPTBN4 | c.5830G>T p.A1944S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.6); catalogued as COSV58949768; called by muse, mutect2, varscan2
- TAS2R38 | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV71885466; called by muse, mutect2, varscan2
- TASOR | c.4757A>G p.D1586G (on ENST00000355628 / NM_001365636.2; = p.D1210G on NM_015224.3) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV58304070; called by muse, mutect2, varscan2
- TMC7 | c.1883C>T p.S628L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs201572722, COSV58583638; called by muse, mutect2, varscan2
- TMEM71 | c.775G>A p.A259T (on ENST00000523829 / NM_001382398.1; = p.A240T on NM_144649.3) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV63457410; called by muse, mutect2, varscan2
- TPTE2 | c.1117-1G>C p.X373_splice (on ENST00000400230 / NM_199254.2; = p.X296_splice on NM_130785.3) | Splice Site (SNP) | VAF 5/26 reads (19%) | catalogued as rs372632566, COSV55023254; called by muse, varscan2
- UMODL1 | c.2447G>A p.R816Q (on ENST00000408910 / NM_001004416.2; = p.R944Q on NM_173568.3) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV68569841; called by muse, mutect2, varscan2
- VPS35 | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54478735; called by muse, mutect2, varscan2
- WNT9A | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs749997833, COSV55294622; called by muse, varscan2
- ZFAT | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV64738789; called by muse, mutect2, varscan2
- ZFC3H1 | c.4710G>C p.K1570N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV66432700; called by muse, mutect2, varscan2
- ZNF691 | c.313C>G p.H105D (on ENST00000372502; = p.H74D on NM_015911.3) | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV65289316; called by muse, mutect2, varscan2
- ZNF785 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs779711522, COSV67876340; called by muse, mutect2, varscan2
- ELF3 | c.687dup p.D230Rfs*5 | Frame Shift Ins (INS) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- OR11H1 | c.514T>G p.F172V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- ACACA | c.1338G>A p.V446= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs1453662580; called by muse, mutect2, varscan2
- AS3MT | c.549C>T p.F183= | Silent (SNP) | VAF 53/116 reads (46%) | catalogued as COSV54916961; called by muse, mutect2, varscan2
- BZW2 | c.765G>A p.R255= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV51755139; called by muse, mutect2
- CCNA1 | c.996G>A p.L332= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV55221671; called by muse, mutect2, varscan2
- CIT | c.2142G>A p.L714= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV55869231; called by muse, mutect2, varscan2
- DLG2 | c.762A>G p.E254= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs1189711020, COSV54645317; called by muse, mutect2, varscan2
- DNAJC6 | c.2259C>T p.N753= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs771875633, COSV54775119; called by muse, mutect2, varscan2
- EPPK1 | c.3939G>C p.L1313= | Silent (SNP) | VAF 57/87 reads (66%) | catalogued as rs781938095, COSV73260786; called by muse, mutect2, varscan2
- FOXN1 | c.1188C>A p.L396= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV56884213, COSV99881373; called by muse, mutect2, varscan2
- GIT1 | c.2271A>G p.R757= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV56402532; called by muse, mutect2, varscan2
- GRIP1 | c.1251G>C p.L417= (on ENST00000359742 / NM_001379345.1; = p.L365= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV54023029; called by muse, mutect2, varscan2
- HERC6 | c.1494G>A p.K498= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV52030196; called by muse, mutect2, varscan2
- KIAA2026 | c.3894A>T p.P1298= | Silent (SNP) | VAF 45/65 reads (69%) | catalogued as COSV67354971; called by muse, mutect2, varscan2
- OR2Z1 | c.189C>T p.L63= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV60692457; called by muse, mutect2, varscan2
- PCDHB7 | c.2007C>T p.P669= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV50769177; called by muse, mutect2, varscan2
- PLXNA4 | c.5247C>T p.V1749= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV58126931; called by muse, mutect2, varscan2
- PYHIN1 | c.777G>A p.L259= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV63722506; called by muse, mutect2, varscan2
- TAOK3 | c.1446G>A p.L482= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV66825907; called by muse, mutect2, varscan2
- TAS2R38 | c.201G>A p.L67= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV71885468; called by muse, mutect2, varscan2
- TLR9 | c.2145C>T p.F715= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs141394433; called by muse, mutect2, varscan2
- TMEM26 | c.90G>A p.V30= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV67492794; called by muse, mutect2, varscan2
- TNS4 | c.837G>A p.V279= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV54185079; called by muse, varscan2
- TRBV5-1 | c.120G>A p.L40= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- VAX1 | c.105G>A p.A35= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs373928197; called by muse, mutect2, varscan2
- ZNF611 | c.654C>T p.L218= | Silent (SNP) | VAF 52/175 reads (30%) | catalogued as COSV60540943; called by muse, mutect2, varscan2
